Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BJ-01A (Primary Tumor).

SURGICAL PATHOLOGY

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: GYNECOLOGY
Surgeon: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: F WHITE
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

BLADDER, SITE NOT SPECIFIED, BIOPSY
- SQUAMOUS METAPLASIA (SEE COMMENT)
- CYSTITIS CYSTICA

UTERUS, CERVIX, BIOPSY
- INVASIVE SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis), and that I have reviewed and approved this report.

[REDACTED], M.D.

[REDACTED], M.D.

SPECIMEN(S) SUBMITTED

Part 1: BLADDER
Part 2: CERVIX

**HISTORY**

The patient is a [REDACTED] year old woman with cervical cancer and irregular bleeding. Clinical diagnosis: Cervical cancer. Operative procedure: EUA, cysto.

GROSS

The specimens are received in two containers of formalin, each labelled with the [REDACTED]. The first container is labelled "bladder biopsy." It contains seven fragments of tan-gray, soft, mucosal tissue measuring 1.2 x 1.0 x 0.2 cm. in aggregate. Inked and wrapped.

The second container is labelled "cervical biopsy." It contains two fragments of pink-gray, soft, mucosal tissue measuring 1.5 x 0.7 x 0.5 cm. in aggregate.

Source: NCI Genomic Data Commons file 3bae30f0-cad4-46c9-8534-6a995134b0e4 (TCGA-C5-A1BJ.9F012D5B-DF59-43C3-96FC-4E6EE55BDAD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).